Somatic mutation profile of tumor specimen TCGA-DJ-A1QI-01A (aliquot TCGA-DJ-A1QI-01A-11D-A14W-08) from TCGA case TCGA-DJ-A1QI, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 63.2 years (23,072 days).
Specimen TCGA-DJ-A1QI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67f8cf64-2e26-4b52-9555-7766d7dce95c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QI-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QI-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d92cad3d-bc98-4066-bf17-149a4d1748c0

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANKAR | c.3271C>G p.L1091V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV55614921; called by muse, mutect2, varscan2
- IGF1R | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.954); catalogued as COSV51310304; called by muse, mutect2
- OR2H2 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV63543295; called by muse, mutect2, varscan2
- SP4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV56024122; called by muse, mutect2, varscan2
- STXBP5L | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs368965958; called by muse, mutect2, varscan2
- GLG1 | c.401del p.N134Tfs*11 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- C10orf53 | c.228T>C p.G76= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV65107870; called by muse, mutect2
- PCCA | c.378C>G p.A126= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV66194397; called by muse, mutect2
